Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5504, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5504-01A (Primary Tumor).

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: The patient is a [REDACTED] with biopsied established prostatic adenocarcinoma [REDACTED]. Gleason score 3+4=7 (left lobe) and Gleason score 3+5 = 8 (right lobe). Serum PSA level is 8.6 ng/ml. The clinical stage is cT2c.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymph node dissection.

SPECIFIC CLINICAL QUESTION: Not stated.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION: No.

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

TCGA-EJ-5504

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, EXCISION -

- A. SINGLE SMALL FOCUS OF METASTATIC PROSTATIC ADENOCARCINOMA PRESENT ON ONE OF FIVE (1/5) LYMPH NODES (SLIDE 1/A).
- B. METASTATIC FOCUS MEASURES APPROXIMATELY 0.15 CM.
- C. NO EXTRACAPSULAR EXTENSION IS IDENTIFIED.

PART 2: LEFT PELVIC LYMPH NODES, EXCISION -

- A. THIRTEEN BENIGN LYMPH NODES (0/13).
- B. NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATITIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 4 + 3 = 7 WITH TERTIARY GLEASON PATTERN 5 COMPONENT, EXTENSIVELY INVOLVING THE PROSTATE GLAND BILATERALLY. GLEASON PATTERNS 4/5 COMPONENTS COMPRISE SLIGHTLY GREATER THAN 50% OF THE SAMPLED PROSTATE TUMOR VOLUME.
- B. MAXIMAL TUMOR DIAMETER IS 1.8 CM IN A HISTOLOGIC SECTION (SLIDE 3/SS).
- C. CARCINOMA COMPRISES APPROXIMATELY 50% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. ESTABLISHED EXTRACAPSULAR EXTENSION IS PRESENT IN THE RIGHT POSTERIOR MID PROSTATE (SLIDES 3/AA, 3/BB), AND PERI-SEMINAL VESICLE SOFT TISSUES ON THE RIGHT (SLIDE 3/A) AND LEFT (SLIDE 3/C) SIDES.
- E. CARCINOMATOUS PERINEURAL INVASION IS IDENTIFIED (SLIDES 3/Z, 3/AA, 3/HH, 3/II).
- F. PRESUMED ANGIOLYMPHATIC INVASION IS PRESENT (SEE PART 1).
- G. ALL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- H. CARCINOMA EXTENSIVELY INFILTRATES RIGHT AND LEFT SEMINAL VESICLES (SLIDES 3/A, 3/C). BILATERAL VASA DEFERENTIA ARE BENIGN.
- I. NO DEFINITE HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. NON-NEOPLASTIC PROSTATE TISSUE WITH NO SPECIFIC ABNORMALITY.
- K. TNM PATHOLOGIC STAGE: T3a, N1, Mx.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 8.6
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	55%
WEIGHT OF PROSTATE:	49.85gm
TUMOR SIZE:	Maximum dimension: 1.8 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	No
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	18
LYMPH NODES POSITIVE:	1
EXTRANODAL EXTENSION:	No
SIZE OF NODAL METASTASIS:	1.5mm
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 75393914-b369-455c-ba6c-347f1c9dacd5 (TCGA-EJ-5504.74F98316-075F-45E1-9BCA-3D885A070FA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).